Gene-level copy-number profile of tumor specimen TCGA-12-0616-01A from TCGA case TCGA-12-0616, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 36.8 years (13,451 days).
Specimen TCGA-12-0616-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.c515d71e-b01b-425c-b305-a285e75acdd1.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-12-0616-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f6526656-616f-4c27-9c3e-a81e7017a647

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 7,833; copy number 2: 50,906; copy number 3: 960; copy number 4: 2; copy number 5: 21; copy number 7: 2; copy number 8: 1; copy number 9: 9; copy number 10: 13; copy number 12: 15; copy number 14: 9; copy number 15: 15; copy number 16: 1; copy number 17: 5; copy number 19: 1; copy number 24: 2; copy number 25: 1; copy number 29: 13; copy number 31: 6; copy number 36: 4.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-12-0616-01A-01D-0310-01): tumor purity 0.86, ploidy 1.93, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 118 genes in 26 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:109,346,326–109,347,459, 1 gene, copy number 25: RBMXP4.
- chr4:137,751,029–137,755,300, 1 gene, copy number 24: AC131956.3.
- chr7:21,381,363–21,381,506, 1 gene, copy number 14: RNU1-15P.
- chr7:37,683,796–38,230,670, 7 genes, copy number 10 (within-gene range 3–10): GPR141, EPDR1, GPR141BP, AC018634.1, NME8, SFRP4, STARD3NL.
- chr7:53,926,676–55,260,256, 20 genes, copy number 9–12 (within-gene range 3–12): LINC02854, AC092848.2, AC092848.1, LINC01445, SLC25A5P3, VSTM2A, VSTM2A-OT1, AC011228.1, RNU6-1125P, RPL31P35, AC011228.3, AC011228.2, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2.
- chr7:57,270,839–57,275,197, 1 gene, copy number 24: AC099654.3.
- chr7:69,507,510–69,597,493, 2 genes, copy number 7: Y_RNA, CT66.
- chr7:71,685,452–71,685,747, 1 gene, copy number 8: RN7SKP75.
- chr7:101,562,779–101,629,296, 2 genes, copy number 10: LINC01007, MYL10.
- chr7:101,822,247–101,824,729, 1 gene, copy number 10: AC005096.1.
- chr7:109,660,094–109,764,357, 2 genes, copy number 10: AC073387.1, AC073387.2.
- chr7:116,210,506–116,258,783, 1 gene, copy number 19 (within-gene range 2–19): TES.
- chr7:116,672,196–116,954,334, 8 genes, copy number 15: MET, CAPZA2, AC002543.1, Y_RNA, RNA5SP239, ST7-AS1, AC106873.5, AC106873.7.
- chr7:116,954,480–116,972,911, 6 genes, copy number 15: AC106873.3, AC106873.2, AC106873.6, AC106873.4, AC106873.1, TPM3P1.
- chr7:120,141,016–120,227,213, 2 genes, copy number 9 (within-gene range 3–9): AC004946.1, AC004946.2.
- chr7:133,727,368–133,733,595, 2 genes, copy number 9: COX5BP3, RPS3AP27.
- chr7:144,849,755–144,850,084, 1 gene, copy number 10: RN7SKP174.
- chr11:23,403,805–23,521,202, 5 genes, copy number 17: WIZP1, MIR8054, AC100767.1, THAP12P4, AC068472.1.
- chr11:31,369,840–31,509,645, 2 genes, copy number 15–16 (within-gene range 1–16): DNAJC24, IMMP1L.
- chr11:32,387,775–32,458,769, 8 genes, copy number 14 (within-gene range 1–14): WT1, WT1-AS, AL049692.6, AL049692.1, AL049692.5, AL049692.3, AL049692.2, AL049692.4.
- chr12:52,249,300–52,309,163, 1 gene, copy number 29 (within-gene range 2–29): KRT86.
- chr12:52,263,948–52,321,398, 7 genes, copy number 29: AC021066.2, AC021066.1, AC021066.3, KRT81, AC121757.2, AC121757.1, KRT83.
- chr12:52,360,006–52,428,494, 6 genes, copy number 31 (within-gene range 2–31): KRT85, KRT84, AC078865.1, KRT82, AC055736.1, KRT90P.
- chr12:57,516,588–57,756,013, 21 genes, copy number 5: DDIT3, AC022506.1, MIR616, MBD6, DCTN2, KIF5A, PIP4K2C, DTX3, ARHGEF25, AC025165.1, AC025165.6, SLC26A10, B4GALNT1, RPL13AP23, OS9, AC025165.2, AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759.
- chr12:68,805,011–68,850,686, 5 genes, copy number 29: AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2.
- chr12:88,049,016–88,199,887, 4 genes, copy number 36 (within-gene range 2–36): CEP290, RNA5SP364, AC091516.1, TMTC3.

Autosomal genes at a single copy (total copy number 1): 7,833. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
